Somatic mutation profile of tumor specimen C3N-08031-01 (aliquot CPT0470870006) from CPTAC case C3N-08031, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 38.7 years (14,122 days).
Specimen C3N-08031-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bd61eb0-45f2-4472-844e-936c4b2125f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08031-31 (Blood Derived Normal), aliquot CPT0470960006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee5456bf-d193-4097-ae8c-174a31b6a980

The open-access MAF lists 220 somatic variants for this specimen: 140 protein-altering or splice-affecting, 76 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 76, Nonsense Mutation 10, Intron 4, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA13 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.771); catalogued as rs867087150, COSV70025591; called by muse, mutect2
- AC131160.1 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs747639206, COSV57700345; called by muse, mutect2
- AMER3 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.216); catalogued as rs762018995; called by muse, mutect2
- ANKRD30A | c.2144G>A p.G715E (on ENST00000611781; = p.G659E on NM_052997.2) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100653176; called by muse, mutect2
- BDP1 | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 34/600 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1441660115, COSV62430653; called by muse, mutect2
- C3orf22 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1224537017; called by muse, mutect2
- C9 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1410725800; called by muse, mutect2
- CACNA1C | c.3346G>A p.G1116R | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100219323; called by muse, mutect2
- CACNA1H | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs914177997; called by muse, mutect2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2
- CDH5 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV58520513; called by muse, mutect2
- CEACAM6 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 35/611 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.331); catalogued as rs1452460745, COSV52269217; called by muse, mutect2
- CFAP47 | c.7180G>A p.E2394K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as COSV66221302; called by muse, mutect2
- COL11A1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1267946269, COSV62190573; called by muse, mutect2
- CPLX3 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs771688461; called by muse, mutect2, varscan2
- CPO | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.136); catalogued as COSV55941118; called by muse, mutect2
- CSF2RA | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 21/411 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs746550319; called by muse, mutect2
- CSMD1 | c.9353C>T p.S3118F (on ENST00000520002; = p.S3117F on NM_033225.6) | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.354); catalogued as COSV59284313; called by muse, mutect2
- DACT3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 41/598 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.367); catalogued as rs1235839873; called by muse, mutect2
- DNAH7 | c.8435C>T p.P2812L | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56788841; called by muse, mutect2
- DOCK11 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs968944156, COSV52234021, COSV99354160; called by muse, mutect2
- DOK6 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.962); catalogued as COSV101234492, COSV66929801; called by muse, mutect2
- DUOX2 | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 21/488 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101199781; called by muse, mutect2
- EDARADD | c.70G>A p.V24I (on ENST00000334232 / NM_145861.4; = p.V14I on NM_080738.4) | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1446653781; called by muse, mutect2
- FAM83B | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs768677387, COSV60923191; called by muse, mutect2
- FAT3 | c.13369C>T p.H4457Y | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as COSV53116996; called by muse, mutect2
- FBXO22 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs1478566457; called by muse, mutect2
- FCER1A | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 25/388 reads (6%) | catalogued as COSV63666484; called by muse, mutect2
- FGA | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs746940107, COSV57401601; called by muse, mutect2
- GJB5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 35/516 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs759300052; called by muse, mutect2
- GLIS3 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 42/656 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs777175866, COSV60935677; called by muse, mutect2
- GRM7 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs912581178, COSV63142169; called by muse, mutect2
- IL7R | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 25/386 reads (6%) | catalogued as COSV57405450, COSV57405806; called by muse, mutect2
- IRF6 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092349; called by muse, mutect2
- ITIH6 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 44/736 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV99513162; called by muse, mutect2
- KCP | c.1171G>A p.V391I (on ENST00000620378; = p.V448I on NM_001366122.1) | Missense Mutation (SNP) | VAF 126/469 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs376242604; called by muse, mutect2, varscan2
- KIAA1109 | c.11842C>T p.P3948S | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.505); catalogued as COSV52668607; called by muse, mutect2
- LMNTD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 31/389 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as rs745756779, COSV51446490; called by muse, mutect2
- LRP1B | c.9395C>T p.P3132L | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101253427; called by muse, mutect2
- MUC12 | c.2009G>T p.R670L (on ENST00000379442; = p.R527L on NM_001164462.1) | Missense Mutation (SNP) | VAF 135/1341 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.158); catalogued as rs748500533; called by muse, mutect2, varscan2
- MUC2 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs556208983; called by muse, mutect2
- MYH1 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 34/554 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV56844884, COSV56850131; called by muse, mutect2
- NCOA3 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 16/379 reads (4%) | catalogued as COSV59071682, COSV59073327; called by muse, mutect2
- NCOA5 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV51644347; called by muse, mutect2
- NGEF | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV50957250; called by muse, mutect2
- NUP214 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV63912736; called by muse, mutect2
- OR10A6 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 46/572 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV59164661; called by muse, mutect2
- OR1J4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV61590241; called by muse, mutect2
- OR2G3 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100180658; called by muse, mutect2
- OR4K13 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 31/403 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs202203700, COSV59859121; called by muse, mutect2
- OTOA | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 27/391 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs1054046525; called by muse, mutect2
- PEG3 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 45/522 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.417); catalogued as rs1482965198, COSV55639022; called by muse, mutect2
- PGBD5 | c.1184C>T p.S395F (on ENST00000525115; = p.S464F on NM_001258311.2) | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1195112048; called by muse, mutect2
- PGR | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 14/362 reads (4%) | catalogued as COSV54797678; called by muse, mutect2
- PLD2 | c.2460C>T p.F820= | Splice Region (SNP) | VAF 23/310 reads (7%) | catalogued as rs909180329, COSV54005214; called by muse, mutect2
- POF1B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 9/297 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99427399, COSV99427766; called by muse, mutect2
- RASAL1 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55657558; called by muse, mutect2
- RER1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV60384615; called by muse, mutect2
- ROBO2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1489562419, COSV59895738; called by muse, mutect2
- S100A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs368160023; called by muse, mutect2
- SCNN1B | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 23/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56301719; called by muse, mutect2
- SLA2 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468206320, COSV53410416; called by muse, mutect2
- SLC1A6 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1430616951, COSV55667690; called by muse, mutect2
- SLC37A3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs200119569; called by muse, mutect2, varscan2
- SLC41A1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65650037, COSV65650088; called by muse, mutect2
- SLC4A7 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs781094576, COSV55399532; called by muse, mutect2
- SLC7A13 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99879038; called by muse, mutect2
- SLC9A2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); catalogued as rs866054183, COSV52129979; called by muse, mutect2
- SLCO1C1 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.534); catalogued as COSV56870740, COSV56880720; called by muse, mutect2
- SNRNP200 | c.1777T>C p.W593R | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60489893; called by muse, mutect2
- SORBS3 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs897041125; called by muse, mutect2
- SPAG9 | c.3152G>A p.R1051H (on ENST00000262013 / NM_001130528.3; = p.R1037H on NM_003971.6) | Missense Mutation (SNP) | VAF 20/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758599822; called by muse, mutect2
- TINAG | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 23/349 reads (7%) | catalogued as COSV52510715; called by muse, mutect2
- TLL1 | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 12/255 reads (5%) | catalogued as COSV99288597; called by muse, mutect2
- TMEM201 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 16/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61050691; called by muse, mutect2
- TP63 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53199759; called by muse, mutect2
- TTN | c.65104G>A p.D21702N (on ENST00000591111; = p.D14278N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/357 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV100598187; called by muse, mutect2
- UNC79 | c.4546G>A p.E1516K (on ENST00000393151 / NM_001346218.2; = p.E1339K on NM_020818.5) | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs939533326, COSV56379134, COSV56381829; called by muse, mutect2
- XAGE5 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV63568296; called by muse, mutect2
- ZNF469 | c.5266G>A p.D1756N (on ENST00000437464; = p.D1784N on NM_001367624.2) | Missense Mutation (SNP) | VAF 39/600 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.185); catalogued as rs775765033; called by muse, mutect2
- ZNF470 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 40/486 reads (8%) | catalogued as rs558252392; called by muse, mutect2
- ZNF716 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101348452, COSV70782755; called by muse, mutect2
- ZNF804A | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100168607, COSV56451702; called by muse, mutect2
- AP000812.4 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- AQP2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATP2B2 | c.1844G>A p.G615E (on ENST00000352432; = p.G581E on NM_001683.5) | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AXL | c.2483G>A p.G828E (on ENST00000301178 / NM_021913.5; = p.G819E on NM_001699.6) | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.599); called by muse, mutect2
- BICD1 | c.2530A>T p.T844S | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2
- BIRC6 | c.6470G>A p.R2157K | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.273); called by muse, mutect2
- BTBD8 | c.4162G>A p.E1388K (on ENST00000636805 / NM_001376131.1; = p.E875K on NM_015237.4) | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- BTNL2 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.26); called by muse, mutect2
- C8orf34 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 60/615 reads (10%) | SIFT tolerated, low confidence (0.37); called by muse, mutect2, varscan2
- CACNA1D | c.4928G>A p.G1643E (on ENST00000350061 / NM_001128840.3; = p.G1663E on NM_000720.4) | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- CACNA1H | c.6247C>T p.P2083S | Missense Mutation (SNP) | VAF 51/682 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- CACNG6 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CASR | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); called by muse, mutect2
- CHRNA6 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- DGKB | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.9412G>A p.E3138K | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2
- DUSP2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2
- ECSCR | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.013); called by muse, mutect2
- FAM120C | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FAM47A | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 44/611 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.093); called by muse, mutect2
- GOLGA6L2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 52/684 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- GPATCH2 | c.1542A>T p.K514N | Missense Mutation (SNP) | VAF 36/427 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- GPN3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 23/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IDS | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 12/415 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGSF9 | c.1581G>A p.W527* (on ENST00000368094 / NM_001135050.2; = p.W511* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 37/526 reads (7%) | called by muse, mutect2
- KCNQ3 | c.926G>T p.W309L | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA1614 | c.1602G>T p.R534S | Missense Mutation (SNP) | VAF 46/602 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- KYAT3 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRB1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 49/590 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC17 | c.5317C>T p.P1773S | Missense Mutation (SNP) | VAF 31/710 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- MYH7B | c.3124A>T p.K1042* | Nonsense Mutation (SNP) | VAF 29/562 reads (5%) | called by muse, mutect2
- MYO15A | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2
- NCAPG | c.2855-1G>A p.X952_splice | Splice Site (SNP) | VAF 17/281 reads (6%) | called by muse, mutect2
- NCAPG | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OPN1SW | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- OR13C3 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- OR2S2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.285); called by muse, mutect2
- OR6C3 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 26/431 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARD6G | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- PPFIA2 | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R18 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 47/631 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SGMS1 | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.169); called by muse, mutect2
- SGO2 | c.390C>T p.F130= | Splice Region (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2, varscan2
- SHROOM3 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 48/523 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SMC1B | c.3434C>T p.P1145L | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SORBS3 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- SPTBN4 | c.3519G>A p.W1173* | Nonsense Mutation (SNP) | VAF 20/485 reads (4%) | called by muse, mutect2
- TAB1 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- TERF2 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 46/586 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2
- TJP1 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TPPP2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 27/576 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRDV2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.26); called by muse, mutect2
- TSSC4 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 43/556 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- VTN | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ZDHHC18 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF581 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 40/553 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ABCA2 | c.4701G>A p.S1567= (on ENST00000614293; = p.S1537= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/566 reads (6%) | catalogued as rs746227428; called by muse, mutect2
- ABCC5 | c.540C>T p.I180= | Silent (SNP) | VAF 54/632 reads (9%) | called by muse, mutect2
- AC099489.1 | c.3504C>T p.A1168= | Silent (SNP) | VAF 32/548 reads (6%) | catalogued as rs1427132238; called by muse, mutect2
- ADGRF5 | c.1560G>A p.R520= | Silent (SNP) | VAF 15/398 reads (4%) | called by muse, mutect2
- ANHX | c.309C>T p.Y103= | Silent (SNP) | VAF 44/532 reads (8%) | called by muse, mutect2
- ANKS1B | c.87G>A p.G29= | Silent (SNP) | VAF 40/470 reads (9%) | catalogued as rs369308498; called by muse, mutect2
- APOB | c.987C>T p.L329= | Silent (SNP) | VAF 28/464 reads (6%) | catalogued as rs773721528; called by muse, mutect2
- ARHGAP6 | c.945C>T p.L315= | Silent (SNP) | VAF 38/622 reads (6%) | catalogued as rs765462924, COSV57298682; called by muse, mutect2
- CAMK1G | c.537C>T p.A179= | Silent (SNP) | VAF 17/311 reads (5%) | called by muse, mutect2
- CAMKV | c.333C>T p.I111= | Silent (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- CARD11 | c.2532G>A p.V844= | Silent (SNP) | VAF 29/1015 reads (3%) | catalogued as rs1185269859; called by muse, mutect2
- CCDC185 | c.1803C>T p.P601= | Silent (SNP) | VAF 40/390 reads (10%) | catalogued as rs1418866381; called by muse, mutect2, varscan2
- CCDC54 | c.816C>T p.I272= | Silent (SNP) | VAF 34/368 reads (9%) | called by muse, mutect2
- CDC14A | c.1692C>T p.I564= | Silent (SNP) | VAF 30/653 reads (5%) | called by muse, mutect2
- CELA3B | c.696C>T p.V232= | Silent (SNP) | VAF 43/548 reads (8%) | catalogued as rs372476706; called by muse, mutect2
- CIB2 | c.252G>A p.G84= | Silent (SNP) | VAF 133/562 reads (24%) | called by muse, mutect2, varscan2
- COL6A3 | c.498G>A p.K166= | Silent (SNP) | VAF 29/514 reads (6%) | called by muse, mutect2
- CPD | c.2754C>T p.L918= | Silent (SNP) | VAF 22/397 reads (6%) | called by muse, mutect2
- CPLX3 | c.219G>A p.R73= | Silent (SNP) | VAF 107/429 reads (25%) | called by muse, mutect2, varscan2
- CYLC1 | c.1584C>T p.S528= | Silent (SNP) | VAF 40/466 reads (9%) | catalogued as COSV61416156; called by muse, mutect2
- DLEC1 | c.2235C>T p.I745= | Silent (SNP) | VAF 30/434 reads (7%) | catalogued as rs1416055722, COSV57297742; called by muse, mutect2
- DNAH6 | c.4809C>T p.A1603= | Silent (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- DNAH7 | c.8637G>A p.L2879= | Silent (SNP) | VAF 38/436 reads (9%) | catalogued as COSV56763447; called by muse, mutect2
- DNAH9 | c.11328C>T p.F3776= | Silent (SNP) | VAF 13/393 reads (3%) | catalogued as COSV52366681; called by muse, mutect2
- DUSP8 | c.825C>T p.F275= | Silent (SNP) | VAF 13/339 reads (4%) | catalogued as COSV59029706; called by muse, mutect2
- EGLN3 | c.556C>T p.L186= | Silent (SNP) | VAF 28/460 reads (6%) | called by muse, mutect2
- EHD2 | c.51C>T p.A17= | Silent (SNP) | VAF 26/552 reads (5%) | catalogued as rs1427416380; called by muse, mutect2
- EPC1 | c.1344C>T p.P448= | Silent (SNP) | VAF 44/542 reads (8%) | catalogued as COSV99553464; called by muse, mutect2
- EPHA3 | c.1233C>T p.A411= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as COSV60694979; called by muse, mutect2
- FAM47C | c.363G>A p.V121= | Silent (SNP) | VAF 45/760 reads (6%) | catalogued as COSV100792530; called by muse, mutect2
- FLNB | c.3336C>T p.L1112= | Silent (SNP) | VAF 28/432 reads (6%) | catalogued as rs149404157; called by muse, mutect2
- GABPB2 | c.1126C>T p.L376= | Silent (SNP) | VAF 20/568 reads (4%) | catalogued as COSV64460936; called by muse, mutect2
- GASK1A | c.451C>T p.L151= | Silent (SNP) | VAF 32/501 reads (6%) | catalogued as rs1559404663; called by muse, mutect2
- GPR152 | c.801C>T p.V267= | Silent (SNP) | VAF 34/524 reads (6%) | catalogued as rs1018548389; called by muse, mutect2
- KIF25 | c.1068C>T p.F356= (on ENST00000354419 / NM_030615.2; = p.F304= on NM_005355.3) | Silent (SNP) | VAF 37/632 reads (6%) | catalogued as rs770880704, COSV63027562; called by muse, mutect2
- KLHL12 | c.57C>T p.I19= | Silent (SNP) | VAF 20/345 reads (6%) | called by muse, mutect2
- LMNB2 | c.1566C>T p.I522= | Silent (SNP) | VAF 32/412 reads (8%) | called by muse, mutect2
- LRP5 | c.2808C>T p.P936= | Silent (SNP) | VAF 36/480 reads (8%) | catalogued as rs1450831341; called by muse, mutect2
- LRRTM3 | c.1701C>T p.I567= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as rs778141715; called by muse, mutect2
- LY86 | c.27C>T p.F9= | Silent (SNP) | VAF 30/356 reads (8%) | catalogued as COSV57911574; called by muse, mutect2
- MAN2A2 | c.2478C>T p.V826= | Silent (SNP) | VAF 75/317 reads (24%) | catalogued as COSV64640014; called by muse, mutect2, varscan2
- MEI1 | c.1926G>A p.E642= | Silent (SNP) | VAF 31/354 reads (9%) | called by muse, mutect2
- MEI4 | c.1065C>T p.F355= | Silent (SNP) | VAF 31/356 reads (9%) | catalogued as rs1374407796; called by muse, mutect2
- MTCH1 | c.177G>A p.Q59= | Silent (SNP) | VAF 24/626 reads (4%) | called by muse, mutect2
- MYOF | c.6120C>T p.F2040= | Silent (SNP) | VAF 28/461 reads (6%) | catalogued as rs772809321, COSV100825170; called by muse, mutect2
- NGFR | c.771C>T p.S257= | Silent (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- NHS | c.903G>A p.P301= | Silent (SNP) | VAF 40/535 reads (7%) | catalogued as rs745327335, COSV66273476; ClinVar: likely benign; called by muse, mutect2
- OR13A1 | c.363C>T p.F121= | Silent (SNP) | VAF 52/682 reads (8%) | catalogued as rs866486835, COSV100981090; called by muse, mutect2
- OR2L3 | c.897C>T p.A299= | Silent (SNP) | VAF 29/436 reads (7%) | catalogued as COSV100742046, COSV63455876; called by muse, mutect2
- OR7G3 | c.450C>T p.I150= | Silent (SNP) | VAF 36/538 reads (7%) | catalogued as rs529517536, COSV59640067; called by muse, mutect2
- PCDHA8 | c.1068C>T p.S356= | Silent (SNP) | VAF 26/403 reads (6%) | called by muse, mutect2
- PKD2L2 | c.39G>A p.S13= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as COSV51799586; called by muse, mutect2
- PLG | c.342G>A p.T114= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as rs776970597, COSV51980374; called by muse, mutect2
- PPP3R2 | c.177C>T p.I59= | Silent (SNP) | VAF 32/540 reads (6%) | catalogued as COSV62455252; called by muse, mutect2
- RADIL | c.2703C>T p.C901= | Silent (SNP) | VAF 70/1042 reads (7%) | catalogued as rs778783914; called by muse, mutect2
- SASH1 | c.2232C>T p.L744= | Silent (SNP) | VAF 21/262 reads (8%) | called by muse, mutect2
- SCNN1A | c.1587G>A p.K529= | Silent (SNP) | VAF 32/506 reads (6%) | called by muse, mutect2
- SEPTIN6 | c.351T>C p.P117= | Silent (SNP) | VAF 38/415 reads (9%) | called by muse, mutect2
- SFPQ | c.756C>T p.H252= | Silent (SNP) | VAF 32/570 reads (6%) | catalogued as rs764896059; called by muse, mutect2
- SLC39A12 | c.1170C>T p.F390= | Silent (SNP) | VAF 29/460 reads (6%) | catalogued as COSV101070194; called by muse, mutect2
- SPECC1L | c.582C>T p.T194= | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- TAF5 | c.168C>T p.S56= | Silent (SNP) | VAF 58/560 reads (10%) | catalogued as rs1230088237; called by muse, mutect2, varscan2
- THBS1 | c.816C>A p.I272= | Silent (SNP) | VAF 31/530 reads (6%) | catalogued as COSV52951052; called by muse, mutect2
- TIAM1 | c.2301C>T p.S767= | Silent (SNP) | VAF 31/564 reads (5%) | catalogued as rs780930906; called by muse, mutect2
- TIAM1 | c.687C>T p.A229= | Silent (SNP) | VAF 76/492 reads (15%) | called by muse, mutect2, varscan2
- TP63 | c.1122G>A p.T374= | Silent (SNP) | VAF 19/317 reads (6%) | catalogued as rs754089583, COSV53224045; called by muse, mutect2
- TRAV9-2 | c.210G>A p.T70= | Silent (SNP) | VAF 34/372 reads (9%) | catalogued as rs554640975; called by muse, mutect2
- TRHDE | c.2163C>T p.I721= | Silent (SNP) | VAF 23/368 reads (6%) | catalogued as rs771321069, COSV53857323; called by muse, mutect2
- TRIOBP | c.3246T>C p.F1082= | Silent (SNP) | VAF 24/430 reads (6%) | catalogued as COSV60374107; called by muse, mutect2
- TUBA3C | c.702C>T p.I234= | Silent (SNP) | VAF 46/692 reads (7%) | catalogued as rs142245280; called by muse, mutect2
- VEGFC | c.1101G>A p.Q367= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- VTN | c.447C>T p.P149= | Silent (SNP) | VAF 32/508 reads (6%) | catalogued as rs1555583642, COSV56873937; called by muse, mutect2
- WWC2 | c.1707C>T p.P569= | Silent (SNP) | VAF 32/377 reads (8%) | called by muse, mutect2
- XIRP2 | c.4323G>A p.R1441= (on ENST00000628543; = p.R1616= on NM_152381.6) | Silent (SNP) | VAF 15/380 reads (4%) | catalogued as COSV54702766, COSV99744317; called by muse, mutect2
- ZBBX | c.225G>A p.L75= | Silent (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2
- ZNF534 | c.1260G>A p.G420= (on ENST00000332323 / NM_001143939.3; = p.G407= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/566 reads (8%) | catalogued as rs973690608, COSV56517203; called by muse, mutect2
- CTBP2 | c.58+12710A>G | Intron (SNP) | VAF 48/688 reads (7%) | called by muse, mutect2
- KCNQ1 | c.1393+21675C>T | Intron (SNP) | VAF 18/346 reads (5%) | called by muse, mutect2
- OPLAH | c.2511+16C>T | Intron (SNP) | VAF 43/346 reads (12%) | catalogued as rs782729282, COSV70677992; called by muse, mutect2, varscan2
- PLCH2 | c.2959+295G>A | Intron (SNP) | VAF 56/653 reads (9%) | called by muse, mutect2
